TCGA case TCGA-AA-3715 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Epithelial Neoplasms; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e394e9ec-7288-4ede-9ef8-41b631d100dd

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 77 years; Vital status: Dead; Days to death: 579 days (1.6 years).

Diagnoses (4)
1. Adenosquamous carcinoma (the primary disease): ICD-O-3 morphology code: 8560/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 77.8 years (28,428 days); Year of diagnosis: 2006; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 579 days (1.6 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 12; Lymphatic invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the bladder (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Prior malignancy of the kidney (histology not recorded by GDC). AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 78.3 years (28,581 days); Days to diagnosis: 153 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS.

Follow-up (3 entries)
- Days to follow up: 30 days; Disease response: With Tumor.
- Day 153 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 153 days.
- Follow-up contact recording only the day: day 579.

Molecular and laboratory tests
- CEA: 7.05 ng/mL.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-3715-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-AA-3715-01A-01-BS1: Section location: Bottom; Percent tumor cells: 94; Percent tumor nuclei: 90; Percent necrosis: 1; Percent stromal cells: 5; Percent lymphocyte infiltration: 1.
  Slide TCGA-AA-3715-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 19; Percent necrosis: 1; Percent lymphocyte infiltration: 5.
- Sample TCGA-AA-3715-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-AA-3715-10A, TCGA-AA-3715-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 7.05; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Kidney; Other malignancy histological type: malignant neoplasm of kidney, except renal pelvis.
- Other malignancy form 1, Surgery: Days from index date to other malignancy surgery: -1492.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Bladder; Other malignancy histological type: malignant neoplasm of bladder.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -5995.

GDC annotations on this case (curator notes; quoted as recorded):
- Item may not meet study protocol: This case was accepted into TCGA but the pathology report is not consistent with study specific metrics. The BCR will ICD code per the pathology report, which may not match the clinical data.
- Prior malignancy: Prior malignancy kidney and bladder cancers. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 579 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 579 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 153 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-3715-01A-01D-0903-01): tumor purity 0.48, ploidy 2.17, whole-genome doublings 0.
